Gene-level copy-number profile of specimen HCM-BROD-0417-C71-85A from HCMI case HCM-BROD-0417-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,275 days).
Specimen HCM-BROD-0417-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3e894a37-c15a-4b36-b196-90fd7e34970c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0417-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/6281bf8a-93b2-4dce-8bae-d4671eb81104

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 36; copy number 2: 11,094; copy number 3: 23,091; copy number 4: 18,317; copy number 5: 1,276; copy number 6: 3,927; copy number 7: 377; copy number 8: 58; copy number 9: 88; copy number 10: 52; copy number 11: 18; copy number 12: 18; copy number 14: 43; copy number 16: 1; copy number 17: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 657 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,545,796–151,545,891, 1 gene, copy number 7 (within-gene range 6–7): MIR554.
- chr4:53,377,641–57,724,655, 95 genes, copy number 8–17 (broad region; genes not listed).
- chr9:31,644,576–32,334,354, 3 genes, copy number 7–8: HMGB3P23, RNA5SP281, SLC25A5P8.
- chr12:100,009,052–100,199,783, 9 genes, copy number 7–8 (within-gene range 6–8): RPS4XP1, AC126474.1, UHRF1BP1L, AC126474.2, AC010203.2, GOLGA2P5, RN7SL176P, AC010203.1, MIR1827.
- chr12:100,357,074–101,386,618, 13 genes, copy number 7: SLC17A8, NR1H4, AC010200.1, GAS2L3, PIGAP1, ANO4, AC138360.1, AC063947.1, SNX5P2, SLC5A8, RNU6-768P, AC079953.1, UTP20.
- chr12:102,073,103–102,463,491, 7 genes, copy number 7–8 (within-gene range 6–8): NUP37, PARPBP, PMCH, HELLPAR, RN7SL793P, AC093023.1, LINC02456.
- chr12:106,015,897–118,833,536, 283 genes, copy number 7–10 (broad region; genes not listed).
- chr12:118,981,541–119,163,051, 2 genes, copy number 7 (within-gene range 6–7): SRRM4, AC087885.1.
- chr12:119,031,039–122,147,344, 109 genes, copy number 7 (broad region; genes not listed).
- chr12:124,725,524–127,826,286, 65 genes, copy number 7–10 (broad region; genes not listed).
- chr12:132,618,776–132,761,832, 9 genes, copy number 7–10: P2RX2, AC131212.4, POLE, PXMP2, AC135586.2, PGAM5, RNA5SP379, ANKLE2, AC135586.1.
- chr14:106,723,574–106,762,588, 2 genes, copy number 10: IGHV2-70D, IGHV1-69D.
- chr19:34,949,038–35,169,881, 18 genes, copy number 11: AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5.
- chr19:38,199,836–38,852,347, 38 genes, copy number 14 (within-gene range 3–14): AC011479.2, RN7SL663P, DPF1, SPINT2, PPP1R14A, AC011479.1, AC011479.4, Y_RNA, YIF1B, C19orf33, KCNK6, CATSPERG, AC005625.1, PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2.
- chr19:44,094,339–44,134,822, 3 genes, copy number 7: ZNF224, AC021092.1, ZNF225.

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
